Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A8CV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A8CV-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE: RECEIVED DATE: REPORT DATE:

COPY TO:

Pre-Op Diagnosis
Endometrial cancer
Post-Op Diagnosis
Nothing indicated on requisition
Clinical History
Nothing indicated on requisition
Gross Description:
Three parts

Container 1 labeled "left pelvic lymph nodes." Received in formalin is a 7.0 x 4.0 x 2.0 cm aggregate of multiple pieces of fatty tissue. Sectioning reveals multiple lymph nodes up to 5.0 cm in greatest dimension. All lymph nodes are submitted in cassettes labeled as follows: A - two intact lymph nodes, B - one quadrisectioned lymph node, C - one trisectioned lymph node, D - one sectioned lymph node in toto, E and F - one sectioned lymph node in toto, G - one sectioned lymph node in toto, H through J - one sectioned lymph node in toto.

Container 2 labeled "right pelvic lymph nodes." Received in formalin is an 8.2 x 5.7 x 1.7 cm aggregate of multiple pieces of fatty tissue. Sectioning reveals multiple lymph nodes up to 4.6 cm in greatest dimension. All lymph nodes are submitted in cassettes labeled as follows: A - two intact lymph nodes, B - one trisectioned lymph node, C - one bisected lymph node, D and E - one sectioned lymph node in toto, F through H - one sectioned lymph node in toto.

Container 3 labeled "uterus, bilateral tubes, bilateral ovaries, cervix." Received in formalin is a 79.4 gram, 6.5 x 5.0 x 4.0 cm uterus with attached cervix, attached 8.8 gram right adnexa, and attached 7.6 gram left adnexa. The ectocervix is surfaced by

CHC ICD O-3
Adenocarcinoma, endometrial
NOS 8880/3
path
Carcinoma, endometrial NOS:
8880/3
Site Endometrium C54.1
JW 4/12/14

[page 2 of 3]
pink tan to slightly violaceous mucosa. The uterine serosa is smooth and tan brown. The endocervical canal is tan and corrugated. The endometrial cavity is 3.5 cm in width and 3.5 cm in length and gives rise to a 4.5 x 3.0 x 2.0 cm exophytic friable tan white tumor. The tumor does not grossly involve the low uterine segment. On section, the tumor extends approximately 0.7 cm into the myometrium where the myometrium is 1.7 cm thick.

The right adnexa consists of a 4.5 cm long x 0.3 cm diameter previously fallopian tube attached to the mesovarium of a 2.4 x 1.2 x 1.1 cm smooth tan white ovary. On section the ovarian stroma is homogeneously yellow tan. The left adnexa consists of a 4.4 cm long x 0.5 cm diameter fallopian tube attached to the mesovarium of a 2.3 x 1.0 x 1.0 cm smooth yellow tan ovary. The ovarian stroma is homogeneously yellow tan. Separate in the container there is a 0.9 x 0.7 x 0.5 cm encapsulated yellow tan nodule. On section the nodule is centrally ascitic. Representative sections are submitted for genomic studies in two cassettes labeled ' '. Representative sections of the remaining tissue are submitted in cassettes labeled " " as follows: A - representative anterior cervix, B - representative posterior cervix, C - representative anterior lower uterine segment, D - representative posterior lower uterine segment, E through G - anterior endomyometrium with tumor, H through J - posterior endomyometrium with tumor, H to include greatest depth of invasion, K through N - sectioned entire right parametrium, O and P - sectioned entire left parametrium, Q - representative right ovary, R - representative right fallopian tube, S - representative left ovary, T - representative left fallopian tube, U - trisected separately submitted nodule.

Microscopic Description:
Slides reviewed.

Final Diagnosis

Left pelvic lymph node dissection:

Eight benign regional lymph nodes (0/8).

Right pelvic lymph node dissection:

Six benign regional lymph nodes (0/6).

Hysterectomy:

Carcinoma of endometrium.

Tumor characteristics:

Histologic type: Endometrioid.

Grade: Moderately differentiated (G2)

Location: Endometrial cavity as a whole.

Extent of invasion: Invades more than one half of the myometrium.

Maximal thickness of myometrial invasion is 11 mm into a 17 mm thick myometrium.

Extension of tumor: Does not extend beyond endometrial cavity.

Lymphovascular space invasion: Not identified.

Surgical margin status:

Cervical margin: Negative.

Left parametrial margin: Negative.

Right parametrial margin: Negative.

Lymph node status (utilizing all specimens):

Sites: Bilateral pelvic.

Number of lymph nodes examined: 14

Number of lymph nodes containing metastatic carcinoma: 0 (0/14)

Other:

Endocervix: No pathologic diagnosis.

[page 3 of 3]
Endometrium: Complex hyperplasia with atypia.
Myometrium: Leiomyoma.
Uterine serosa: Focal endometriosis.
Bilateral fallopian tubes and ovaries: No pathologic diagnosis.

Benign appendix epiploica.
Stage: pT1bN0

CPT: 88309, 88307 x2

Comments

This test has been finalized at the [REDACTED]

<Sign Out Dr. Signature>

HPV Discrepancy		✓

Source: NCI Genomic Data Commons file 2070d2be-e362-4092-93f1-271c6bf35f65 (TCGA-AJ-A8CV.9A08EA28-EF0B-40CE-B2B4-0A0B0EE1EDA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).